Somatic mutation profile of tumor specimen TCGA-2H-A9GI-01A (aliquot TCGA-2H-A9GI-01A-11D-A37C-09) from TCGA case TCGA-2H-A9GI, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 68.7 years (25,097 days).
Specimen TCGA-2H-A9GI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83658ca8-38ef-48c9-8320-f892af3af092.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2H-A9GI-11A (Solid Tissue Normal), aliquot TCGA-2H-A9GI-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/209c33a4-6399-4f2a-82c0-6a16122aa33f

The open-access MAF lists 214 somatic variants for this specimen: 154 protein-altering or splice-affecting, 48 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 135, Silent 48, Nonsense Mutation 9, Intron 8, Frame Shift Ins 7, RNA 3, Splice Region 1, Frame Shift Del 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAH | c.615dup p.V206Cfs*18 | Frame Shift Ins (INS) | VAF 13/41 reads (32%) | catalogued as rs1057517084; ClinVar: likely pathogenic; called by mutect2, varscan2
- PPM1D | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 32/51 reads (63%) | catalogued as rs779070661, CM1414538, COSV59954404; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALK | c.2732A>G p.K911R | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.092); catalogued as COSV66566749; called by muse, mutect2, varscan2
- AVP | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1221046393; called by muse, mutect2, varscan2
- AZI2 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs957731886, COSV99843582; called by muse, mutect2, varscan2
- BRINP1 | c.1609T>G p.F537V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.055); catalogued as rs762203463, COSV56292541; called by muse, mutect2, varscan2
- CDK12 | c.2726G>T p.G909V | Missense Mutation (SNP) | VAF 247/268 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71002618; called by muse, mutect2, varscan2
- CELSR3 | c.5548G>A p.D1850N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.913); catalogued as rs146491964; called by muse, mutect2, varscan2
- CHRNG | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1171659636, COSV51330557; called by muse, mutect2, varscan2
- CHST9 | c.1009T>G p.L337V | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV104370430; called by muse, mutect2, varscan2
- CSMD1 | c.9853G>A p.A3285T (on ENST00000520002; = p.A3284T on NM_033225.6) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs566623371; called by muse, mutect2, varscan2
- CTTNBP2 | c.4661A>G p.D1554G | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as rs1562947751; called by muse, mutect2, varscan2
- DCDC1 | c.4191A>C p.Q1397H (on ENST00000597505 / NM_001367979.1; = p.Q504H on NM_020869.3) | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100338804; called by muse, mutect2, varscan2
- DLC1 | c.2279C>T p.T760M (on ENST00000276297 / NM_001348081.2; = p.T323M on NM_006094.5) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs144923726, COSV104371038; called by muse, mutect2, varscan2
- ECHDC1 | c.76C>G p.Q26E (on ENST00000531967 / NM_001139510.1; = p.Q20E on NM_018479.3) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.058); catalogued as COSV58932247; called by muse, mutect2, varscan2
- FANCD2 | c.3238C>G p.Q1080E | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs1411877055; called by muse, mutect2, varscan2
- FAT3 | c.5527A>T p.T1843S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.189); catalogued as COSV99961070, COSV99973046; called by muse, mutect2, varscan2
- FAT3 | c.12103A>G p.S4035G | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs1383313219; called by muse, mutect2, varscan2
- FMN2 | c.5045T>G p.L1682R | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV60419417, COSV60456884; called by muse, mutect2, varscan2
- FOLH1 | c.2154A>C p.K718N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV57047514; called by muse, mutect2, varscan2
- GABRA6 | c.727T>G p.F243V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV50887688; called by muse, mutect2, varscan2
- GABRG1 | c.1277C>A p.S426Y | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV54951926, COSV54961565; called by muse, mutect2, varscan2
- GATAD2A | c.1714G>A p.V572M | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as rs372533863; called by muse, mutect2, varscan2
- GLI3 | c.4432G>A p.E1478K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1241442383, CM107040; called by muse, mutect2, varscan2
- GRM1 | c.2539C>T p.R847C | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51108913, COSV51217462; called by muse, mutect2, varscan2
- GRM4 | c.2074C>T p.R692C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs778877648; called by muse, mutect2, varscan2
- H1-5 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.14); catalogued as COSV100137595; called by muse, mutect2, varscan2
- IGHV4-61 | c.15G>T p.W5C | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.045); catalogued as rs372670777; called by muse, varscan2
- ITGAD | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as rs749387931, COSV66757223; called by muse, mutect2, varscan2
- KIF2B | c.411C>A p.S137R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV52127037, COSV52134855; called by muse, mutect2, varscan2
- LAMA1 | c.3758A>C p.N1253T | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.831); catalogued as COSV67535853; called by muse, mutect2, varscan2
- LCA5L | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs370755758; called by muse, mutect2, varscan2
- LMO1 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs747347634; called by muse, mutect2, varscan2
- LRP1B | c.9625G>A p.V3209I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.956); catalogued as rs77794732, COSV67231336, COSV67250866, COSV67284629; called by mutect2, varscan2
- LRP1B | c.9083T>G p.I3028S | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV101257737; called by muse, mutect2, varscan2
- MMP9 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 78/130 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1055327031, COSV63434262; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO15A | c.10507C>T p.R3503C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753532529, COSV52761652; called by muse, mutect2, varscan2
- MYOM2 | c.2343C>A p.Y781* | Nonsense Mutation (SNP) | VAF 45/87 reads (52%) | catalogued as COSV50703156; called by muse, mutect2, varscan2
- NRG2 | c.640dup p.L214Pfs*19 | Frame Shift Ins (INS) | VAF 27/70 reads (39%) | catalogued as rs762297999; called by mutect2, pindel, varscan2
- OR2T12 | c.668T>G p.V223G | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58777346, COSV58779751; called by muse, mutect2, varscan2
- OR51F1 | c.506T>G p.L169R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as COSV100598875, COSV58578784; called by muse, mutect2, varscan2
- OR5I1 | c.101T>C p.L34P | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766067213; called by muse, mutect2, varscan2
- OR5L2 | c.661A>C p.I221L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV65723674; called by muse, mutect2, varscan2
- OR7G2 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs201831795, COSV59687968; called by muse, mutect2, varscan2
- PLEK | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as rs200352669, COSV52250616, COSV52252675; called by muse, mutect2, varscan2
- PRL | c.644A>G p.K215R | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as COSV100123129; called by muse, mutect2, varscan2
- RALYL | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs147345564; called by muse, mutect2, varscan2
- RBM42 | c.289C>G p.Q97E | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs762869265; called by muse, mutect2, varscan2
- RYR3 | c.1927C>T p.R643W | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747174943, COSV66778985; called by muse, mutect2, varscan2
- SACS | c.5855T>G p.V1952G | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV66547826; called by muse, mutect2, varscan2
- SCN10A | c.2106C>T p.I702= | Splice Region (SNP) | VAF 4/16 reads (25%) | catalogued as rs1308782974; called by muse, mutect2, varscan2
- SLITRK4 | c.329A>C p.K110T | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs782212814, COSV62025521, COSV62025809; called by muse, mutect2, varscan2
- SNX21 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs767723058; called by muse, mutect2
- SNX33 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV57913052; called by muse, mutect2, varscan2
- STX16 | c.899G>A p.R300Q (on ENST00000371141 / NM_001001433.3; = p.R279Q on NM_003763.6) | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs780151862; called by muse, mutect2, varscan2
- STX17 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs780746142; called by muse, mutect2, varscan2
- SYNE1 | c.3736G>A p.E1246K (on ENST00000367255 / NM_182961.4; = p.E1253K on NM_033071.3) | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.13); catalogued as rs138915528; called by muse, mutect2, varscan2
- TAS2R60 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.84); PolyPhen benign (0.127); catalogued as COSV60332423; called by muse, mutect2, varscan2
- TBC1D23 | c.1947A>C p.K649N (on ENST00000394144 / NM_001199198.3; = p.K634N on NM_018309.5) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs760618915, COSV61366454, COSV61366703; called by muse, mutect2, varscan2
- TPH2 | c.992A>C p.K331T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV61590489, COSV61591680, COSV61594179; called by muse, mutect2, varscan2
- TRIM6 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748199490, COSV53475055; called by muse, mutect2, varscan2
- TRIOBP | c.5519G>A p.R1840H (on ENST00000644935 / NM_001039141.3; = p.R127H on NM_007032.5) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376340052, CM1310691; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.89164G>A p.V29722I (on ENST00000591111; = p.V22298I on NM_003319.4) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | PolyPhen benign (0.01); catalogued as COSV59877924; called by muse, mutect2, varscan2
- TTN | c.47816A>C p.D15939A (on ENST00000591111; = p.D8515A on NM_003319.4) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | PolyPhen benign (0.111); catalogued as COSV60225029; called by muse, mutect2, varscan2
- TTN | c.31809A>C p.K10603N (on ENST00000591111; = p.K9676N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/106 reads (21%) | PolyPhen benign (0.31); catalogued as COSV59925588; called by muse, mutect2, varscan2
- USP29 | c.1637A>C p.K546T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs187226665, COSV54142095; called by muse, mutect2, varscan2
- USP42 | c.3896G>A p.R1299Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs368427289; called by muse, mutect2, varscan2
- XIRP1 | c.1603C>T p.R535W | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs749599115, COSV61140971; called by muse, mutect2, varscan2
- ZFP30 | c.956T>G p.L319R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1315879634, COSV63622729; called by muse, mutect2, varscan2
- ZNF486 | c.1243T>C p.Y415H | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs1555718368; called by muse, mutect2, varscan2
- ACSM5 | c.1652G>T p.R551M | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ADAMTS9 | c.3197T>G p.V1066G | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADCY6 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRV1 | c.10691A>C p.N3564T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, varscan2
- ALPK3 | c.3205C>T p.L1069F | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ANKRD28 | c.658A>G p.S220G | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- ATP10A | c.1789T>G p.F597V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ATP11B | c.1539G>A p.W513* | Nonsense Mutation (SNP) | VAF 27/41 reads (66%) | called by muse, mutect2, varscan2
- BRINP1 | c.1430T>G p.F477C | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- CAPN5 | c.1967A>G p.N656S (on ENST00000456580; = p.N616S on NM_004055.5) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBFA2T3 | c.1649A>C p.E550A | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CDCA2 | c.1727_1734dup p.G579Lfs*27 | Frame Shift Ins (INS) | VAF 12/58 reads (21%) | called by mutect2, varscan2
- CDH18 | c.524G>A p.G175D | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CHP2 | c.125A>C p.K42T | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- COL6A5 | c.7414A>C p.T2472P (on ENST00000312481; = p.T2468P on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- CPSF3 | c.1098C>G p.H366Q | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DCAF4L2 | c.436T>C p.F146L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX11 | c.734A>T p.E245V | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DERL2 | c.68C>G p.A23G | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.443); called by muse, mutect2
- DMBT1 | c.3106T>C p.C1036R (on ENST00000338354 / NM_001377530.1; = p.C537R on NM_004406.3) | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- DSP | c.7697G>A p.G2566D | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DUS2 | c.605C>G p.A202G | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- DYNC2H1 | c.9113T>G p.L3038R | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EHD3 | c.139T>C p.S47P | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT4 | c.13387A>G p.T4463A | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- FBXO7 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GCN1 | c.4220G>T p.G1407V | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GEMIN4 | c.1486A>C p.N496H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPLD1 | c.2378C>A p.S793Y | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- GRIK2 | c.791T>G p.L264R | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.194A>T p.E65V | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2
- IGHV4-61 | c.14G>A p.W5* | Nonsense Mutation (SNP) | VAF 16/114 reads (14%) | called by muse, varscan2
- IGKV3D-20 | c.25T>A p.F9I | Missense Mutation (SNP) | VAF 116/161 reads (72%) | SIFT tolerated (0.41); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- INVS | c.1741C>A p.L581I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KDM4A | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- KIF2B | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 36/58 reads (62%) | called by muse, mutect2, varscan2
- KIF2B | c.1514A>G p.D505G | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- KLHL31 | c.1718G>A p.W573* | Nonsense Mutation (SNP) | VAF 35/53 reads (66%) | called by muse, mutect2, varscan2
- LAMA1 | c.4861G>A p.G1621S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.91); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LAYN | c.161A>G p.Y54C (on ENST00000375615 / NM_001258390.1; = p.Y46C on NM_178834.5) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LMF2 | c.1875G>A p.W625* | Nonsense Mutation (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2, varscan2
- LRP1B | c.12208T>G p.L4070V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- MAGEE1 | c.1972A>G p.R658G | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MPPED2 | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- MRC1 | c.3862C>G p.P1288A | Missense Mutation (SNP) | VAF 22/394 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.429); called by muse, mutect2
- MUC13 | c.1067_1070dup p.S357Rfs*14 | Frame Shift Ins (INS) | VAF 8/47 reads (17%) | called by mutect2, pindel, varscan2
- MUC16 | c.11660A>C p.N3887T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- NBAS | c.6422C>T p.P2141L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- NDST3 | c.206A>G p.K69R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NEFH | c.1320C>A p.S440R | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- NELL1 | c.2113A>G p.S705G | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- NLGN4Y | c.787T>A p.L263M | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOL4 | c.806A>G p.E269G | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- NPEPL1 | c.1204A>G p.R402G | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- OR10J1 | c.401T>G p.V134G | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- OR2B3 | c.769T>G p.Y257D | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- OR4C15 | c.389T>G p.I130S (on ENST00000314644; = p.I76S on NM_001001920.2) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- OR4P4 | c.487T>C p.F163L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR8J3 | c.164T>G p.L55R | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OSR1 | c.717_720dup p.C241Ifs*38 | Frame Shift Ins (INS) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- PCNX3 | c.2335G>A p.A779T | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- PHACTR2 | c.31del p.A11Lfs*3 | Frame Shift Del (DEL) | VAF 13/72 reads (18%) | called by mutect2, pindel, varscan2
- PHF1 | c.58dup p.S20Ffs*24 | Frame Shift Ins (INS) | VAF 12/79 reads (15%) | called by mutect2, pindel, varscan2
- POMZP3 | c.484A>T p.K162* | Nonsense Mutation (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- RGS12 | c.2462G>A p.R821H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- RPS6KA5 | c.1568A>G p.Y523C | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- SAGE1 | c.1856G>A p.R619K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- SDR16C5 | c.410G>C p.C137S | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.4); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SLC6A2 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMARCC2 | c.3569-2_3570del p.X1190_splice | Splice Site (DEL) | VAF 27/75 reads (36%) | called by mutect2, pindel, varscan2
- SORCS3 | c.1349T>C p.V450A | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TBC1D8 | c.1211C>A p.T404N | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBX20 | c.963A>C p.E321D | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- TGOLN2 | c.1159G>T p.A387S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- THBD | c.1305C>A p.D435E | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNC | c.3538G>T p.A1180S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, varscan2
- TRPS1 | c.3098A>C p.Q1033P (on ENST00000220888 / NM_001330599.2; = p.Q1046P on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.76291G>T p.E25431* (on ENST00000591111; = p.E18007* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- VAT1L | c.1013T>G p.L338R | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- XDH | c.1546T>G p.F516V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB20 | c.2168A>C p.K723T (on ENST00000474710 / NM_001164342.2; = p.K650T on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZFHX4 | c.1390A>G p.S464G | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.21); called by muse, mutect2
- ZFPM2 | c.1025A>C p.Y342S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ZNF251 | c.171dup p.V58Cfs*3 | Frame Shift Ins (INS) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- ANP32A | c.165C>T p.T55= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs755371580; called by muse, mutect2, varscan2
- ATRNL1 | c.2572T>C p.L858= | Silent (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- CACNA1B | c.372G>A p.T124= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV53128307; called by muse, mutect2, varscan2
- CATIP | c.603C>T p.T201= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs200618385; called by muse, mutect2, varscan2
- CHRNA4 | c.1672C>T p.L558= | Silent (SNP) | VAF 8/190 reads (4%) | called by muse, mutect2
- CST1 | c.417A>G p.Q139= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs768296718; called by muse, mutect2, varscan2
- CTNNA2 | c.1257A>G p.Q419= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV58157947, COSV58167835; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1662C>T p.D554= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs748769090, COSV62567089; called by muse, mutect2, varscan2
- EHD4 | c.1590C>T p.P530= | Silent (SNP) | VAF 28/51 reads (55%) | catalogued as COSV55003281; called by muse, mutect2, varscan2
- EIF2S1 | c.468A>T p.A156= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99833273; called by muse, mutect2, varscan2
- FLRT1 | c.1305C>T p.G435= | Silent (SNP) | VAF 17/20 reads (85%) | catalogued as rs762156219, COSV55367088; called by muse, mutect2, varscan2
- GMNN | c.66A>G p.P22= | Silent (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- GYG2 | c.486G>A p.P162= | Silent (SNP) | VAF 14/23 reads (61%) | called by muse, mutect2, varscan2
- HADHB | c.831A>G p.K277= | Silent (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- HYDIN | c.774G>T p.L258= | Silent (SNP) | VAF 18/29 reads (62%) | called by muse, mutect2, varscan2
- ICAM1 | c.813G>A p.S271= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs200759542; called by muse, mutect2, varscan2
- IGKV1-6 | c.84G>A p.Q28= | Silent (SNP) | VAF 41/167 reads (25%) | catalogued as rs766563678; called by muse, mutect2, varscan2
- IRX1 | c.1374G>T p.P458= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as rs944099410; called by muse, mutect2, varscan2
- KHDRBS3 | c.834T>C p.A278= | Silent (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- LCT | c.2613T>G p.T871= | Silent (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- MAN2B2 | c.498G>A p.A166= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs565418990, COSV99576913; called by muse, mutect2, varscan2
- MICAL3 | c.3189C>T p.S1063= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as rs747550648, COSV71588015; called by muse, mutect2, varscan2
- MUC16 | c.31878T>C p.S10626= | Silent (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2
- MYH6 | c.2532C>T p.S844= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs756736352, COSV62447940; called by muse, mutect2, varscan2
- NAA11 | c.558T>G p.S186= | Silent (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- NME8 | c.1210A>C p.R404= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV52254619, COSV99553357, COSV99553951; called by muse, mutect2, varscan2
- NOXO1 | c.30G>T p.V10= | Silent (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2, varscan2
- NRG1 | c.1227A>G p.R409= (on ENST00000405005 / NM_013964.5; = p.R414= on NM_013956.5) | Silent (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- NRXN2 | c.3366C>T p.C1122= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1477406999; called by muse, mutect2, varscan2
- NUP210 | c.639C>T p.T213= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs773902822, COSV99596058; called by muse, mutect2, varscan2
- OR4S2 | c.48T>C p.S16= | Silent (SNP) | VAF 52/70 reads (74%) | catalogued as rs1313450033, COSV56745460, COSV56747812; called by muse, mutect2, varscan2
- OR5T2 | c.681T>C p.S227= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV57588476, COSV57589308, COSV57590451; called by muse, mutect2, varscan2
- OR5T3 | c.285C>A p.V95= | Silent (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- P2RY1 | c.69G>A p.S23= | Silent (SNP) | VAF 49/79 reads (62%) | catalogued as COSV100521684; called by muse, mutect2, varscan2
- PCLO | c.5877T>G p.S1959= | Silent (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- PREX2 | c.148T>C p.L50= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV55750189, COSV55751655, COSV99910567; called by muse, mutect2, varscan2
- RFTN1 | c.630G>A p.V210= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs755164726; called by muse, mutect2, varscan2
- RIMS2 | c.1794A>G p.G598= (on ENST00000666250 / NM_001348490.2; = p.G406= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV99156869; called by muse, mutect2, varscan2
- SEZ6L | c.330G>A p.K110= | Silent (SNP) | VAF 32/97 reads (33%) | called by muse, mutect2, varscan2
- SIN3A | c.678T>C p.H226= | Silent (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- SLIT2 | c.2913T>C p.T971= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV99888356; called by muse, mutect2, varscan2
- SNTG2 | c.1114T>C p.L372= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV57984512, COSV57995286, COSV58009247; called by muse, mutect2, varscan2
- SPATA32 | c.453G>A p.A151= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs144068330; called by muse, mutect2, varscan2
- STXBP2 | c.600G>A p.Q200= | Silent (SNP) | VAF 30/60 reads (50%) | called by muse, mutect2, varscan2
- TMEM37 | c.117C>T p.V39= | Silent (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- TUBA3C | c.813C>A p.T271= | Silent (SNP) | VAF 68/105 reads (65%) | called by muse, mutect2, varscan2
- UPF3A | c.1293G>A p.L431= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs1287830057; called by muse, mutect2, varscan2
- ZNF681 | c.652A>C p.R218= | Silent (SNP) | VAF 27/81 reads (33%) | called by muse, mutect2, varscan2
- CMAS | c.-1G>A | 5'UTR (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- HTR2C | c.-80+16966A>G | Intron (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1729-19T>G | Intron (SNP) | VAF 19/42 reads (45%) | catalogued as COSV68924090; called by muse, mutect2, varscan2
- NTRK3 | c.1890-1776A>G | Intron (SNP) | VAF 14/67 reads (21%) | catalogued as COSV62306034; called by muse, mutect2, varscan2
- PTPRK | c.2492-1422A>T | Intron (SNP) | VAF 20/82 reads (24%) | called by muse, mutect2, varscan2
- PTPRK | c.2492-1423G>A | Intron (SNP) | VAF 19/80 reads (24%) | catalogued as rs1222707333; called by muse, mutect2, varscan2
- RGS6 | c.1368+3785G>A | Intron (SNP) | VAF 24/45 reads (53%) | catalogued as rs748964422, COSV59578253; called by muse, mutect2, varscan2
- RIMS2 | c.4064-21190G>T | Intron (SNP) | VAF 23/75 reads (31%) | catalogued as COSV51709647; called by muse, mutect2, varscan2
- SNORD114-19 | n.53G>A | RNA (SNP) | VAF 59/114 reads (52%) | catalogued as rs373309604; called by muse, mutect2, varscan2
- TTN | c.10360+3790C>A | Intron (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100637056; called by muse, mutect2, varscan2
- XIST | n.9619T>G | RNA (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- ZNF658B | n.2372T>A | RNA (SNP) | VAF 20/100 reads (20%) | called by mutect2, varscan2
